Somatic mutation profile of tumor specimen TARGET-20-PASMYS-09A (aliquot TARGET-20-PASMYS-09A-03D) from TARGET case TARGET-20-PASMYS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (768 days).
Specimen TARGET-20-PASMYS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfa9d7a1-d794-4455-8204-cd593a57ff8a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMYS-14A (Bone Marrow Normal), aliquot TARGET-20-PASMYS-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3112139e-6653-4759-9f00-caf4a6e77fa2

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: In Frame Del 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT5B | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 85/264 reads (32%) | catalogued as rs1565212298, COSV58566478; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.8138G>A p.R2713Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs771083100, COSV99306316; called by muse, mutect2
- KIT | c.1248_1256delinsATT p.T417_D419delinsF | In Frame Del (DEL) | VAF 59/203 reads (29%) | catalogued as COSV55391318, COSV55397899; called by pindel, varscan2*
